Gene-level copy-number profile of tumor specimen TCGA-AJ-A3TW-01A from TCGA case TCGA-AJ-A3TW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 78.2 years (28,559 days).
Specimen TCGA-AJ-A3TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.cc378541-b512-464b-adaf-484d457b1339.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3TW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47335102-0533-45d6-b33b-d22aad89103a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,049; copy number 2: 19,426; copy number 3: 20,416; copy number 4: 9,486; copy number 5: 3,447; copy number 6: 1,790; copy number 7: 1,359; copy number 8: 143; copy number 9: 245; copy number 10: 132; copy number 11: 39; copy number 12: 75; copy number 14: 44; copy number 15: 78; copy number 21: 37; copy number 23: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3TW-01A-11D-A227-01): tumor purity 0.63, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,150 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,072,710–40,240,921, 4 genes, copy number 8 (within-gene range 3–8): PPT1, OAZ1P1, RLF, RNU6-1237P.
- chr3:80,163,327–83,437,728, 21 genes, copy number 7: OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1.
- chr3:88,948,142–90,261,708, 10 genes, copy number 7: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:167,392,796–198,222,513, 612 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr6:3,693,923–7,251,980, 77 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:17,224,243–17,706,925, 10 genes, copy number 10 (within-gene range 6–10): AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P.
- chr6:21,664,185–22,654,455, 1 gene, copy number 7 (within-gene range 6–7): CASC15.
- chr6:22,133,205–23,404,132, 10 genes, copy number 7: NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1.
- chr7:56,011,051–62,275,678, 111 genes, copy number 7 (broad region; genes not listed).
- chr8:86,866,415–88,019,113, 8 genes, copy number 7 (within-gene range 6–7): CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1.
- chr10:4,201,141–4,515,244, 6 genes, copy number 7 (within-gene range 4–7): LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P.
- chr10:35,778,302–38,719,229, 58 genes, copy number 7: PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5.
- chr11:8,391,868–13,758,345, 119 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:15,112,424–15,930,951, 8 genes, copy number 9 (within-gene range 4–9): INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682.
- chr11:15,969,533–15,969,621, 1 gene, copy number 9: MIR6073.
- chr11:19,350,724–20,121,601, 1 gene, copy number 8 (within-gene range 5–8): NAV2.
- chr11:19,502,672–20,659,285, 16 genes, copy number 8: NAV2-AS5, NAV2-AS4, MIR4486, AC023950.1, AC009549.1, MIR4694, NAV2-AS3, NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5.
- chr11:20,670,425–21,000,997, 2 genes, copy number 8: AC090707.1, RNA5SP336.
- chr11:43,680,680–43,856,617, 1 gene, copy number 23 (within-gene range 3–23): HSD17B12.
- chr11:43,827,517–47,330,031, 96 genes, copy number 15–23 (within-gene range 4–23) (broad region; genes not listed).
- chr11:62,832,234–64,304,770, 78 genes, copy number 7 (broad region; genes not listed).
- chr18:21,612,314–23,026,488, 40 genes, copy number 14: SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:25,061,924–28,177,946, 43 genes, copy number 11–14 (within-gene range 1–14): ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.
- chr19:14,514,769–17,821,574, 186 genes, copy number 9 (broad region; genes not listed).
- chr19:20,122,569–21,793,860, 75 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr19:27,638,483–40,950,660, 512 genes, copy number 7–21 (broad region; genes not listed).
- chr20:46,859,333–47,786,616, 20 genes, copy number 8 (within-gene range 6–8): RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1.
- chr21:21,566,763–23,432,282, 24 genes, copy number 7–10: AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 1,712. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
